PECGS case C083-000077 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/b840628f-d6ce-43b1-b112-ba7546105185

Demographics
Sex at birth: male; Age at index: 46 years; Year of birth: 1977; Vital status: Dead; Education level: College Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Age at diagnosis: 45.7 years (16,692 days); AJCC clinical stage: Stage IV; Progression or recurrence: no.

Biospecimens (2 samples)
- Sample C083-000077_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000077_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
